Somatic mutation profile of tumor specimen 3d797911-d476-436f-9cce-33e20c (aliquot 3d797911-d476-436f-9cce-33e20c_D6) from CPTAC case 11CO018, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 3d797911-d476-436f-9cce-33e20c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7357ea04-d9ac-4403-9f47-d369949d18f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7b852609-7cc7-4950-b18a-423b86 (Blood Derived Normal), aliquot 7b852609-7cc7-4950-b18a-423b86_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4fc705d-7208-42fd-ad86-f8c0cc5f25e8

The open-access MAF lists 2,872 somatic variants for this specimen: 1,941 protein-altering or splice-affecting, 540 silent, 391 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,241, Silent 540, Frame Shift Del 469, Intron 213, Frame Shift Ins 84, 3'UTR 66, Nonsense Mutation 64, RNA 37, Splice Site 35, 5'UTR 34, Splice Region 24, 5'Flank 22.

Variants (750 of 2,872; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 82/288 reads (28%) | catalogued as rs1085307154, CM085286, COSV65809003; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHEK2 | c.1031del p.L344Wfs*3 (on ENST00000382580 / NM_001005735.2; = p.L301Wfs*3 on NM_007194.4) | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | catalogued as rs748005072, CD159815; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 58/184 reads (32%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 101/441 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs797044875, CM162169, COSV62690253; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 72/318 reads (23%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 74/468 reads (16%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.3054del p.T1019Pfs*38 | Frame Shift Del (DEL) | VAF 79/311 reads (25%) | catalogued as rs1554424138; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MITF | c.1048T>C p.S350P (on ENST00000448226 / NM_006722.3; = p.S250P on NM_000248.4) | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893744, CM950795; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 80/360 reads (22%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- OTOGL | c.3760del p.Y1254Ifs*3 (on ENST00000547103; = p.Y1245Ifs*3 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1064795124; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 47/178 reads (26%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.4094del p.G1365Efs*33 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | catalogued as rs587784375, COSV62107582; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 42/166 reads (25%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- TRPS1 | c.2755G>A p.A919T (on ENST00000220888 / NM_001330599.2; = p.A932T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518972, CM010488, COSV99628169; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.911del p.F304Sfs*12 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs776887626; called by pindel, varscan2
- ABCA7 | c.4790T>C p.I1597T | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs373332305; called by muse, mutect2, varscan2
- ABCC11 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62325182; called by muse, mutect2, varscan2
- ABCG1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304552863, COSV59202798; called by muse, mutect2, varscan2
- ABHD16A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 100/194 reads (52%) | catalogued as COSV104424989, COSV65451653; called by muse, mutect2, varscan2
- ABL1 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59328408; called by muse, varscan2
- AC097637.1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs999721192, COSV59725868; called by muse, varscan2
- AC126283.2 | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764739067; called by muse, mutect2, varscan2
- ACAD11 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV53900481; called by muse, mutect2, varscan2
- ACTG1 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 160/631 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59509952; called by muse, mutect2, varscan2
- ACTL8 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368004903, COSV64860988; called by muse, mutect2, varscan2
- ACTR3B | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as rs1563161481; called by muse, mutect2, varscan2
- ACTRT1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs138430204; called by muse, mutect2, varscan2
- ACVR1B | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1182074710; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | catalogued as rs767549806; called by pindel, varscan2*
- ADAMTS5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757685984, COSV53175432; called by muse, mutect2, varscan2
- ADCY6 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs778820517, COSV57166444, COSV57170721; called by muse, mutect2, varscan2
- ADCY6 | c.1086del p.E363Kfs*3 | Frame Shift Del (DEL) | VAF 65/279 reads (23%) | catalogued as rs1565648463; called by mutect2, pindel, varscan2
- ADCY7 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs769391894; called by muse, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 46/86 reads (53%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA2 | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs1228938865; called by muse, mutect2, varscan2
- ADRB1 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.154); catalogued as rs1371090340; called by muse, mutect2
- AEBP1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747457242; called by muse, mutect2, varscan2
- AFF3 | c.926T>A p.M309K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1356968145; called by muse, mutect2, varscan2
- AGPAT4 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs115545633; called by muse, mutect2, varscan2
- AIRE | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.237); catalogued as rs771592755; called by muse, mutect2, varscan2
- AKAP13 | c.4742G>A p.R1581Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779545910; called by muse, mutect2, varscan2
- AKR1D1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs112849023; called by muse, mutect2, varscan2
- ALG9 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369262620; called by muse, mutect2
- ALKBH4 | c.460T>C p.C154R | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748049809; called by muse, mutect2, varscan2
- ALKBH6 | c.242G>A p.R81H (on ENST00000252984 / NM_001297701.2; = p.R109H on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/467 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs1194699256, COSV53324121, COSV53325024; called by muse, mutect2, varscan2
- ALOX12B | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV59871477; called by muse, mutect2, varscan2
- AMDHD2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs868440881; called by muse, varscan2
- AMDHD2 | c.1216G>A p.A406T (on ENST00000293971 / NM_001330449.2; = p.A436T on NM_015944.4) | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1467310280, COSV53550335; called by muse, mutect2, varscan2
- AMER3 | c.1669dup p.A557Gfs*54 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs756385870; called by mutect2, varscan2
- AMH | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs749993067; called by muse, varscan2
- AMIGO3 | c.400del p.A134Rfs*47 | Frame Shift Del (DEL) | VAF 77/309 reads (25%) | catalogued as COSV57539582; called by mutect2, pindel, varscan2
- AMOT | c.2118-1G>T p.X706_splice (on ENST00000371959 / NM_001113490.1; = p.X297_splice on NM_133265.3) | Splice Site (SNP) | VAF 28/48 reads (58%) | catalogued as COSV59069038; called by muse, mutect2, varscan2
- AMOTL2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372900931; called by muse, mutect2, varscan2
- AMPD3 | c.648dup p.N217Qfs*17 (on ENST00000396553 / NM_001025389.2; = p.N226Qfs*17 on NM_000480.3) | Frame Shift Ins (INS) | VAF 80/372 reads (22%) | catalogued as rs1298240902; called by mutect2, varscan2
- ANK1 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 141/513 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs147741842; called by muse, mutect2, varscan2
- ANK2 | c.7697A>G p.H2566R | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV52170370; called by muse, mutect2, varscan2
- ANKK1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1436982215; called by muse, mutect2, varscan2
- ANKK1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 134/549 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as rs751344795; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD31 | c.1407del p.E470Kfs*3 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs1171871289; called by mutect2, pindel, varscan2
- ANKRD34B | c.627del p.F209Lfs*22 | Frame Shift Del (DEL) | VAF 45/231 reads (19%) | catalogued as rs1360099247; called by mutect2, pindel, varscan2
- ANO3 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.869); catalogued as rs141456844, COSV56797891; called by muse, mutect2, varscan2
- AP001054.1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 136/496 reads (27%) | catalogued as rs371141104; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 76/253 reads (30%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- APC | c.8383G>A p.A2795T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.408); catalogued as rs369264968, CM080057; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- APOE | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM064979; called by muse, mutect2, varscan2
- ARHGAP25 | c.599G>A p.R200H (on ENST00000409202 / NM_001007231.3; = p.R192H on NM_014882.3) | Missense Mutation (SNP) | VAF 100/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs769542947, COSV54897982; called by muse, mutect2, varscan2
- ARHGAP40 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146978120; called by muse, mutect2, varscan2
- ARHGAP9 | c.1014del p.R339Afs*14 | Frame Shift Del (DEL) | VAF 59/282 reads (21%) | catalogued as rs771769575; called by mutect2, pindel, varscan2
- ARHGEF10L | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs753769559, COSV51435177; called by muse, mutect2, varscan2
- ARHGEF18 | c.2657G>A p.R886H (on ENST00000359920 / NM_001130955.2; = p.R782H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1343091521; called by muse, mutect2, varscan2
- ARHGEF2 | c.1322G>A p.R441H (on ENST00000361247 / NM_001162383.2; = p.R413H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/494 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752620262, COSV58116702; called by muse, mutect2, varscan2
- ARHGEF3 | c.253del p.R85Dfs*53 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs1464963794; called by mutect2, pindel, varscan2
- ARHGEF40 | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070255; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 74/300 reads (25%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARL10 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372502997; called by muse, mutect2, varscan2
- ARL13B | c.932del p.N311Ifs*6 (on ENST00000394222 / NM_001174150.2; = p.N204Ifs*6 on NM_144996.4) | Frame Shift Del (DEL) | VAF 33/122 reads (27%) | catalogued as rs750642821; called by mutect2, pindel, varscan2
- ASCC3 | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs187359221; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 58/198 reads (29%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.5396T>C p.V1799A | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as rs747145638; called by muse, mutect2, varscan2
- ASIC3 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as rs1431399377; called by muse, mutect2, varscan2
- ATG3 | c.476-8del | Splice Region (DEL) | VAF 12/50 reads (24%) | catalogued as rs769857068; called by mutect2, pindel, varscan2
- ATG4D | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs761538562; called by muse, mutect2, varscan2
- ATP1A4 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772367102, COSV63629022; called by muse, varscan2
- ATP2B1 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53804833; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as rs757422502; called by muse, varscan2
- ATXN7 | c.2404C>G p.L802V | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs61736568; called by muse, mutect2, varscan2
- AVPR1A | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 150/578 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV54547191; called by muse, mutect2, varscan2
- AXIN1 | c.1523del p.G508Vfs*197 | Frame Shift Del (DEL) | VAF 108/366 reads (30%) | catalogued as rs760961378; called by mutect2, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 78/353 reads (22%) | catalogued as COSV51989295; called by mutect2, pindel, varscan2
- B3GALT1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.369); catalogued as rs749603004, COSV59908153; called by muse, mutect2, varscan2
- B4GALNT4 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201456025; called by muse, mutect2, varscan2
- BABAM2 | c.1089-2A>G p.X363_splice | Splice Site (SNP) | VAF 24/111 reads (22%) | catalogued as rs1158646505; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BBS7 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs200720761, COSV99144958; called by muse, mutect2, varscan2
- BCAS3 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.46); catalogued as rs375099101; called by muse, mutect2, varscan2
- BCORL1 | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54398837; called by muse, mutect2, varscan2
- BCR | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1225685186; called by muse, mutect2, varscan2
- BEND4 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs775677177, COSV101549706; called by muse, mutect2, varscan2
- BEST2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV50378941; called by muse, mutect2, varscan2
- BICD1 | c.2536A>G p.N846D | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs201938950; called by muse, mutect2, varscan2
- BMPR2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs763757383; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 47/170 reads (28%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRD7 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419699976; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSG | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs777381758; called by muse, mutect2, varscan2
- BSN | c.5192C>G p.T1731S | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV56514945; called by muse, mutect2, varscan2
- BTBD8 | c.1886del p.N629Mfs*9 (on ENST00000636805 / NM_001376131.1; = p.N116Mfs*9 on NM_015237.4) | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs774107642; called by mutect2, pindel, varscan2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 41/164 reads (25%) | catalogued as rs774921343; called by mutect2, varscan2
- C11orf16 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.083); catalogued as rs1204277324; called by muse, mutect2, varscan2
- C12orf29 | c.313dup p.W105Lfs*4 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs779611287; called by mutect2, varscan2
- C12orf60 | c.180dup p.E61* | Frame Shift Ins (INS) | VAF 46/206 reads (22%) | catalogued as rs1447010986; called by mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 52/258 reads (20%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C16orf89 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs762467164; called by muse, mutect2, varscan2
- C1QTNF4 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56784199; called by muse, mutect2, varscan2
- C1QTNF4 | c.118del p.L40Wfs*9 | Frame Shift Del (DEL) | VAF 61/282 reads (22%) | catalogued as rs747640589; called by mutect2, pindel, varscan2
- C3orf18 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV99231821; called by muse, mutect2, varscan2
- C3orf20 | c.1309del p.T437Pfs*7 | Frame Shift Del (DEL) | VAF 35/152 reads (23%) | catalogued as rs757962317; called by mutect2, pindel, varscan2
- C4BPA | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV65537374; called by muse, mutect2, varscan2
- C4BPB | c.187dup p.C63Lfs*5 | Frame Shift Ins (INS) | VAF 28/123 reads (23%) | catalogued as rs1378141023; called by mutect2, pindel, varscan2
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs951061763; called by mutect2, varscan2
- CABP1 | c.1073G>A p.R358Q (on ENST00000316803 / NM_001033677.1; = p.R155Q on NM_004276.5) | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.28); catalogued as rs750230085; called by muse, mutect2, varscan2
- CABP4 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444662536; called by mutect2, varscan2
- CABS1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs772622462, COSV56734464; called by muse, mutect2, varscan2
- CACNA1A | c.6613C>T p.R2205W | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477386827, COSV64192200; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1G | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs774433052, COSV61720000; called by muse, mutect2, varscan2
- CACNA1I | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 155/606 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV60819413; called by muse, mutect2, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- CACTIN | c.1819_1821del p.F607del | In Frame Del (DEL) | VAF 29/132 reads (22%) | catalogued as rs751667810; called by pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 52/200 reads (26%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN13 | c.1282dup p.S428Ffs*12 | Frame Shift Ins (INS) | VAF 70/260 reads (27%) | catalogued as rs1479139254; called by mutect2, varscan2
- CAPN5 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated, low confidence (0.76); PolyPhen probably damaging (0.935); catalogued as rs902810927; called by muse, mutect2, varscan2
- CARD10 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52657446; called by muse, mutect2, varscan2
- CARMIL2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1488343405; called by muse, mutect2, varscan2
- CARNS1 | c.2077del p.R693Afs*58 | Frame Shift Del (DEL) | VAF 102/423 reads (24%) | catalogued as COSV57052304; called by mutect2, pindel, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CCBE1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs138986040; called by muse, mutect2, varscan2
- CCDC105 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV52964618; called by muse, mutect2, varscan2
- CCDC130 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs190052129; called by muse, mutect2, varscan2
- CCDC141 | c.3535C>T p.Q1179* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV55368477; called by muse, mutect2, varscan2
- CCDC144A | c.4096A>G p.K1366E | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.159); catalogued as COSV100138578; called by muse, mutect2, varscan2
- CCDC190 | c.825G>C p.E275D | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63363651; called by muse, mutect2, varscan2
- CCDC39 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs528863074; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs751135235; called by mutect2, varscan2
- CCKBR | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 80/414 reads (19%) | catalogued as COSV100582970; called by muse, mutect2, varscan2
- CCNA1 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs963194750; called by muse, mutect2, varscan2
- CD81 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 137/630 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144435973; called by muse, mutect2, varscan2
- CDAN1 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 101/511 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV51157259; called by muse, mutect2, varscan2
- CDC73 | c.787C>A p.R263S | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.782); catalogued as COSV66468152; called by muse, mutect2
- CDCA2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747346434; called by muse, mutect2, varscan2
- CDH15 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 178/788 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs201216557; called by mutect2, varscan2
- CDH2 | c.1808del p.P603Lfs*44 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | catalogued as COSV52272660; called by mutect2, pindel, varscan2
- CDIPT | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54889223; called by muse, mutect2, varscan2
- CDK11B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.723); catalogued as rs1245402769; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs545773596, COSV100575508; called by muse, mutect2, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs753494539; called by mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs759091263; called by mutect2, varscan2
- CDYL | c.460G>A p.V154M (on ENST00000328908 / NM_001368125.1; = p.V100M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/306 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs757700421, COSV59360401; called by muse, mutect2, varscan2
- CELSR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762869620; called by muse, mutect2, varscan2
- CELSR2 | c.6248G>A p.R2083Q | Missense Mutation (SNP) | VAF 127/468 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs760545756; called by muse, mutect2, varscan2
- CEMIP | c.3296G>A p.R1099H | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772930693; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP126 | c.2193del p.E732Kfs*25 | Frame Shift Del (DEL) | VAF 22/139 reads (16%) | catalogued as rs755857306; called by mutect2, pindel, varscan2
- CES3 | c.1316_1317del p.Y439* | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1229872779; called by mutect2, pindel, varscan2
- CFAP74 | c.1714del p.L572Cfs*16 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as rs1367003583; called by mutect2, pindel, varscan2
- CFAP91 | c.1680+14del | Splice Region (DEL) | VAF 88/312 reads (28%) | catalogued as rs1559762565; called by mutect2, varscan2
- CHD3 | c.332del p.K111Rfs*30 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs1382061552; called by mutect2, pindel, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHGB | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 47/181 reads (26%) | catalogued as rs553869356, COSV66759863; called by muse, mutect2, varscan2
- CHRD | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs776496708; called by muse, mutect2, varscan2
- CHRM4 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 87/319 reads (27%) | catalogued as rs1393401639; called by muse, mutect2, varscan2
- CHST8 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); catalogued as rs1224670793, COSV99381552; called by muse, mutect2, varscan2
- CHUK | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1022179742; called by muse, mutect2, varscan2
- CIITA | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 157/591 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751075993, COSV100162636; called by muse, mutect2, varscan2
- CIT | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774914678, COSV55863025, COSV99949497; called by muse, mutect2, varscan2
- CLDN34 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1198913868; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 50/90 reads (56%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPSL2 | c.191T>C p.M64T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100846301; called by muse, varscan2
- CLPTM1L | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs199877453, COSV57989385; called by muse, mutect2, varscan2
- CLTCL1 | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782242284; called by muse, mutect2, varscan2
- CLVS1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 47/187 reads (25%) | catalogued as COSV100369276; called by muse, mutect2, varscan2
- CNDP2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60841836; called by muse, mutect2, varscan2
- CNNM2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.353); catalogued as rs868073270; called by muse, mutect2, varscan2
- CNTN5 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201711104; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 42/156 reads (27%) | catalogued as rs374805044; called by mutect2, varscan2
- COG5 | c.1576-1G>T p.X526_splice | Splice Site (SNP) | VAF 52/222 reads (23%) | catalogued as rs866857981; called by muse, varscan2
- COL11A1 | c.2809-1G>A p.X937_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100617945; called by muse, mutect2, varscan2
- COL1A1 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 138/481 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.1); catalogued as rs779846520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV100279729; called by muse, mutect2, varscan2
- COL5A2 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs575864379, COSV66415924; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL7A1 | c.4485C>T p.G1495= | Splice Region (SNP) | VAF 99/435 reads (23%) | catalogued as rs367958901; called by muse, mutect2, varscan2
- CORIN | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs775507102; called by muse, mutect2, varscan2
- CPSF4 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs149850144; called by muse, mutect2, varscan2
- CPT1A | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750076498; called by muse, mutect2, varscan2
- CPXM2 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1478230543; called by muse, mutect2
- CRAT | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1293095989; called by muse, mutect2, varscan2
- CREBBP | c.4963del p.L1655Cfs*89 | Frame Shift Del (DEL) | VAF 144/635 reads (23%) | catalogued as CD065689, COSV52131212; called by pindel, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | catalogued as rs762650691; called by mutect2, varscan2
- CRYGC | c.475del p.A159Pfs*20 | Frame Shift Del (DEL) | VAF 69/287 reads (24%) | catalogued as rs1271901479; called by mutect2, pindel, varscan2
- CSAD | c.713C>T p.P238L (on ENST00000444623 / NM_001244705.2; = p.P265L on NM_015989.5) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248041143, COSV57245666; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 51/186 reads (27%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSPG4 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs765993758; called by muse, mutect2, varscan2
- CST3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 187/732 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs748275854, COSV65361904; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 44/173 reads (25%) | catalogued as rs767756120; called by mutect2, varscan2
- CSTF2T | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100484362; called by muse, mutect2
- CUBN | c.6847C>T p.R2283W | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs150117913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX2 | c.4286dup p.A1430Cfs*11 | Frame Shift Ins (INS) | VAF 51/221 reads (23%) | catalogued as rs750550645; called by mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs745836350; called by mutect2, varscan2
- CYLC1 | c.1281del p.D428Ifs*65 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV100254340; called by mutect2, varscan2
- CYP1B1 | c.868del p.R290Afs*3 | Frame Shift Del (DEL) | VAF 92/377 reads (24%) | catalogued as COSV99037570; called by mutect2, pindel, varscan2
- DAAM1 | c.1655del p.P552Hfs*32 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs764323288, COSV62837932; called by mutect2, pindel, varscan2
- DBNDD2 | c.562del p.Q188Sfs*12 | Frame Shift Del (DEL) | VAF 82/343 reads (24%) | catalogued as rs1320987043; called by mutect2, pindel, varscan2
- DCAF12L1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 122/224 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs753668766; called by muse, mutect2, varscan2
- DCAF8L1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 170/322 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs757727199, COSV71595234; called by muse, mutect2, varscan2
- DCHS2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.143); catalogued as rs781378668; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX42 | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs945667322, COSV63789771; called by muse, mutect2
- DDX55 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs746538098; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs778036194; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs772416332; called by mutect2, varscan2
- DECR2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs183925447; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 35/169 reads (21%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGKQ | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); catalogued as COSV56616679; called by muse, mutect2, varscan2
- DHDH | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763168931; called by muse, mutect2, varscan2
- DHODH | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372609567; called by muse, mutect2, varscan2
- DHRS7C | c.790C>T p.R264C (on ENST00000330255 / NM_001220493.2; = p.R263C on NM_001105571.3) | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs138811643, COSV100364590; called by muse, varscan2
- DIAPH1 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 136/614 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs769436448; called by muse, varscan2
- DLG2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as rs1414599025, COSV54646625; called by muse, mutect2, varscan2
- DLL3 | c.1772T>C p.L591P | Missense Mutation (SNP) | VAF 92/345 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1164056815, COSV52694505; called by mutect2, varscan2
- DMXL2 | c.326del p.L109* | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs752363479; called by mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 49/179 reads (27%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJA3 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1362089104; called by muse, varscan2
- DNAJC21 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs780572204, COSV57761977; called by muse, mutect2, varscan2
- DNMT1 | c.3347-1G>T p.X1116_splice | Splice Site (SNP) | VAF 20/535 reads (4%) | catalogued as COSV100532853; called by muse, mutect2
- DNTTIP2 | c.1582del p.S528Vfs*22 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | catalogued as COSV63283516; called by mutect2, pindel, varscan2
- DOCK1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1340008027; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK6 | c.5956C>T p.R1986W | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs36059048, COSV53921500; called by muse, mutect2, varscan2
- DOCK6 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs370687038; called by muse, mutect2, varscan2
- DPYSL3 | c.810del p.G271Efs*3 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as COSV58330462; called by mutect2, pindel, varscan2
- DRC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs747739014; called by muse, mutect2, varscan2
- DRC1 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV55506603; called by muse, mutect2, varscan2
- DSEL | c.1958G>T p.S653I | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100026172; called by muse, mutect2, varscan2
- DST | c.5780T>A p.L1927* | Nonsense Mutation (SNP) | VAF 53/224 reads (24%) | catalogued as rs980428529; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs35805169; called by mutect2, pindel, varscan2
- DUOX1 | c.4568del p.P1523Lfs*3 | Frame Shift Del (DEL) | VAF 40/161 reads (25%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DUSP16 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913437254, COSV53806336; called by muse, mutect2, varscan2
- DUSP3 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376755368; called by muse, mutect2, varscan2
- EDNRB | c.667C>T p.R223* (on ENST00000377211 / NM_001201397.1; = p.R133* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 86/367 reads (23%) | catalogued as CM144320; called by muse, mutect2, varscan2
- EFR3B | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1452052060; called by muse, mutect2
- EHD2 | c.501C>T p.R167= | Splice Region (SNP) | VAF 50/193 reads (26%) | catalogued as rs368179494, COSV54408202; called by muse, mutect2, varscan2
- EHD3 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 105/318 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV59032828; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3K | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs375272283; called by muse, mutect2, varscan2
- ELF5 | c.526T>C p.W176R (on ENST00000312319 / NM_198381.2; = p.W166R on NM_001422.4) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193438284; called by muse, mutect2, varscan2
- EME1 | c.1595T>C p.V532A | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1307744446, COSV56814889; called by muse, mutect2
- ENGASE | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs760147289; called by muse, mutect2, varscan2
- ENO3 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1437923645; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs761717176; called by mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPG5 | c.7511G>A p.R2504H | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979554550, COSV56347470; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 42/174 reads (24%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EPPK1 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs117667958; called by muse, mutect2, varscan2
- EPS8L2 | c.1412del p.P471Rfs*49 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV59350488; called by mutect2, pindel, varscan2
- EPX | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 113/453 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs557007012; called by muse, mutect2, varscan2
- ERBIN | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs774913262, COSV52318999; called by muse, mutect2, varscan2
- ERC2 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 56/232 reads (24%) | catalogued as rs764697146; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs753821453; called by mutect2, varscan2
- ESF1 | c.494del p.N165Ifs*24 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs775532281; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3L1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1298577228; called by muse, mutect2, varscan2
- EXT2 | c.806T>C p.L269P (on ENST00000343631; = p.L302P on NM_000401.3) | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1412485749; called by muse, mutect2, varscan2
- F7 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 185/690 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139372641, CM001989; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 88/448 reads (20%) | catalogued as rs766589051; called by pindel, varscan2
- FAM13A | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs537879478; called by muse, mutect2, varscan2
- FAM155A | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs202062814, COSV65586584; called by muse, mutect2, varscan2
- FAM172A | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs780440236; called by muse, mutect2, varscan2
- FAM229B | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as rs1415921615, COSV64087064; called by muse, mutect2, varscan2
- FAM234A | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233579994, COSV56995237; called by muse, mutect2, varscan2
- FAM234A | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs756884001, COSV51451469; called by muse, mutect2, varscan2
- FAM86B1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 69/580 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as rs1459884373; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT3 | c.10955G>A p.R3652H | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV53166350; called by muse, mutect2, varscan2
- FBLL1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as rs1439571972; called by muse, mutect2, varscan2
- FBLN2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 96/387 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs767840890; called by muse, mutect2, varscan2
- FBXO47 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs755139986; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD5 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs1316723114; called by muse, mutect2, varscan2
- FGF6 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406814273; called by mutect2, varscan2
- FIBIN | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.04); catalogued as rs1344331770; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLAD1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295851072; called by muse, mutect2, varscan2
- FLT4 | c.3278C>T p.T1093M | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs770869636, COSV56125072; called by mutect2, varscan2
- FOXRED2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as rs747052892, COSV53401760; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as rs200254754; called by muse, mutect2, varscan2
- FREM1 | c.2875G>A p.V959M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201699523; called by muse, mutect2, varscan2
- FREM2 | c.8824G>A p.D2942N | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs750639083; called by mutect2, varscan2
- FRMD6 | c.673C>T p.R225* (on ENST00000344768 / NM_001267046.2; = p.R217* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 41/123 reads (33%) | catalogued as COSV100655564, COSV61089604; called by muse, mutect2, varscan2
- FRMPD4 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs370344979, COSV66213661; called by muse, mutect2, varscan2
- FRY | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as rs761217786; called by muse, mutect2, varscan2
- FRYL | c.1645del p.E549Kfs*19 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as COSV51962239; called by mutect2, pindel, varscan2
- FSIP2 | c.6643del p.S2215Hfs*16 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as COSV58083498; called by mutect2, pindel, varscan2
- FSIP2 | c.20138del p.L6713Cfs*3 | Frame Shift Del (DEL) | VAF 36/174 reads (21%) | catalogued as COSV58085601; called by mutect2, varscan2
- FYN | c.1514del p.K505Rfs*53 | Frame Shift Del (DEL) | VAF 57/246 reads (23%) | catalogued as COSV57612665, COSV57616025; called by mutect2, pindel, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | catalogued as rs777471402; called by mutect2, pindel
- GALNT17 | c.1097del p.G366Afs*50 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as COSV100351740; called by mutect2, pindel, varscan2
- GARNL3 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 46/183 reads (25%) | catalogued as rs1334370667; called by muse, mutect2, varscan2
- GARS1 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); catalogued as COSV66828038; called by muse, mutect2, varscan2
- GAS2L2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.035); catalogued as rs370173315; called by muse, mutect2, varscan2
- GAS6 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 36/176 reads (20%) | catalogued as rs890027803; called by muse, varscan2
- GATAD2A | c.817del p.R273Gfs*42 | Frame Shift Del (DEL) | VAF 63/247 reads (26%) | catalogued as COSV53067075; called by mutect2, pindel, varscan2
- GCH1 | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CD121725, CM088433; called by muse, mutect2, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 22/237 reads (9%) | catalogued as rs768450027; called by mutect2, pindel
- GDF7 | c.682dup p.R228Pfs*258 | Frame Shift Ins (INS) | VAF 51/123 reads (41%) | catalogued as rs761897305; called by mutect2, varscan2
- GFPT1 | c.1630G>A p.E544K (on ENST00000357308 / NM_001244710.2; = p.E526K on NM_002056.4) | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs755583835, COSV100622862; called by muse, mutect2, varscan2
- GFRA1 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100815872; called by mutect2, varscan2
- GFRA2 | c.613del p.R205Afs*96 | Frame Shift Del (DEL) | VAF 80/358 reads (22%) | catalogued as COSV60780249; called by mutect2, pindel, varscan2
- GIN1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs782269685, COSV67536787; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | catalogued as rs771881138; called by mutect2, varscan2
- GJC1 | c.396_398del p.E132del | In Frame Del (DEL) | VAF 71/232 reads (31%) | catalogued as rs770217465; called by pindel, varscan2
- GLI2 | c.2584C>T p.L862F (on ENST00000361492 / NM_001374353.1; = p.L879F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as rs1337169378; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GMPPA | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867708778, COSV58006444, COSV58006861; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GOLGA4 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62710615; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR158 | c.3502C>T p.R1168* | Nonsense Mutation (SNP) | VAF 63/233 reads (27%) | catalogued as rs755737179, COSV100893899; called by muse, mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 92/352 reads (26%) | catalogued as rs770829884; called by mutect2, varscan2
- GRB14 | c.612dup p.P205Sfs*10 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | catalogued as rs780357659; called by mutect2, varscan2
- GRID2IP | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1234325277; called by muse, mutect2, varscan2
- GRID2IP | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs938281164, COSV101474832; called by muse, mutect2, varscan2
- GRM2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 152/558 reads (27%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.972); catalogued as rs1177196948, COSV56583667; called by muse, mutect2, varscan2
- GRM8 | c.2158dup p.H720Pfs*5 | Frame Shift Ins (INS) | VAF 31/144 reads (22%) | catalogued as rs772717214; called by mutect2, varscan2
- GTF2IRD1 | c.1258C>A p.H420N | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs782014176; called by muse, mutect2, varscan2
- GUCY2D | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs145420245, COSV99643965; called by muse, mutect2, varscan2
- H2BC15 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 78/170 reads (46%) | catalogued as rs759275537; called by pindel, varscan2
- H3C6 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 122/223 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs371874494; called by muse, mutect2, varscan2
- H4C2 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 181/324 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV55137561; called by muse, mutect2, varscan2
- HAAO | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs944388409; called by muse, mutect2, varscan2
- HADH | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 123/510 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs972897276; called by muse, mutect2, varscan2
- HAO1 | c.155G>T p.R52M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373715337; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HAUS8 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs141662392; called by muse, mutect2, varscan2
- HAVCR2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs367655592; called by muse, mutect2, varscan2
- HDAC7 | c.552del p.S185Afs*138 (on ENST00000427332; = p.S224Afs*138 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs1469325700; called by mutect2, pindel, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HERC2 | c.8741G>A p.R2914H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs566182373, COSV99871222; called by muse, mutect2, varscan2
- HERC2 | c.3538C>T p.R1180W | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs555428725; called by muse, mutect2, varscan2
- HIC1 | c.397G>A p.A133T (on ENST00000322941 / NM_001098202.1; = p.A114T on NM_006497.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867843142; called by muse, varscan2
- HID1 | c.2318del p.P773Lfs*8 | Frame Shift Del (DEL) | VAF 62/224 reads (28%) | catalogued as COSV60913992; called by mutect2, pindel, varscan2
- HIRA | c.2944C>T p.R982W | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1556004628; called by muse, mutect2, varscan2
- HIVEP1 | c.6286C>T p.R2096C | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65098922; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 87/245 reads (36%) | catalogued as rs199474609; called by mutect2, varscan2
- HLA-C | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.998); catalogued as rs1482720568; called by muse, mutect2
- HMCN1 | c.6557del p.N2186Tfs*53 | Frame Shift Del (DEL) | VAF 44/173 reads (25%) | catalogued as rs1298533680; called by mutect2, pindel, varscan2
- HMCN2 | c.5935C>A p.L1979I | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV70382307; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPUL1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1362442748; called by muse, mutect2, varscan2
- HOXA3 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1286530524, COSV57829041; called by muse, mutect2, varscan2
- HOXB13 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 109/462 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs1405620801, COSV51707235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXB6 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53314223; called by muse, mutect2, varscan2
- HPCAL1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as rs1320925684; called by muse, mutect2, varscan2
- HSPA9 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as rs372075340; called by muse, mutect2, varscan2
- HSPG2 | c.9959G>A p.C3320Y | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65932993; called by muse, mutect2, varscan2
- HSPG2 | c.1390C>A p.L464M | Missense Mutation (SNP) | VAF 217/918 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65930651; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 53/199 reads (27%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- IBA57 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs914514776; called by muse, mutect2, varscan2
- IBSP | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs758115196, COSV56894829; called by muse, varscan2
- ICAM1 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99320695; called by muse, mutect2, varscan2
- ICAM5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55746245; called by muse, mutect2, varscan2
- IGF1R | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 122/552 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs1330526325; called by muse, varscan2
- IGHV3OR16-8 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 102/468 reads (22%) | catalogued as rs1405121109; called by muse, mutect2, varscan2
- IGSF9 | c.2587del p.Q863Rfs*65 (on ENST00000368094 / NM_001135050.2; = p.Q847Rfs*65 on NM_020789.4) | Frame Shift Del (DEL) | VAF 24/125 reads (19%) | catalogued as rs1228987905; called by mutect2, pindel, varscan2
- IL21R | c.867+2T>C p.X289_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | catalogued as COSV61968752; called by muse, mutect2, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 111/265 reads (42%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- INF2 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 119/458 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs769493931; called by muse, mutect2, varscan2
- INPP5B | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); catalogued as rs185569565; called by muse, mutect2, varscan2
- INPP5F | c.1449A>T p.K483N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62823692; called by muse, mutect2, varscan2
- INSYN1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs771270220, COSV65837394; called by muse, mutect2, varscan2
- INTS5 | c.3011G>A p.G1004D | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as COSV57954175; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs759821884; called by mutect2, varscan2
- IRF6 | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV65420149; called by muse, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 102/244 reads (42%) | catalogued as rs780982673; called by mutect2, varscan2
- IRX3 | c.725del p.G242Afs*18 | Frame Shift Del (DEL) | VAF 55/233 reads (24%) | catalogued as COSV61667883; called by mutect2, pindel, varscan2
- ITGB2 | c.1723G>A p.G575S (on ENST00000302347; = p.G551S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs900964697; called by muse, mutect2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | catalogued as rs760028800; called by mutect2, varscan2
- ITPKA | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs772076582, COSV53027408; called by muse, mutect2, varscan2
- JCAD | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs927198945, COSV64758141; called by muse, mutect2, varscan2
- KAZN | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.218); catalogued as rs773377392; called by muse, varscan2
- KCNC2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54369344; called by muse, mutect2, varscan2
- KCND2 | c.1609dup p.T537Nfs*16 | Frame Shift Ins (INS) | VAF 80/312 reads (26%) | catalogued as rs770990872; called by mutect2, varscan2
- KCNK16 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs555715474, COSV100949359; called by muse, mutect2, varscan2
- KCNK3 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.183); catalogued as rs746544523; called by muse, mutect2, varscan2
- KCNQ3 | c.2469del p.S824Rfs*4 | Frame Shift Del (DEL) | VAF 173/732 reads (24%) | catalogued as COSV101196164; called by mutect2, pindel, varscan2
- KCNS1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs1275304313; called by muse, mutect2
- KCTD7 | c.98_109del p.P33_T36del | In Frame Del (DEL) | VAF 21/90 reads (23%) | catalogued as rs753399965; called by mutect2, varscan2
- KDM1A | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1468810802, COSV100752786, COSV63090424; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs746314511; called by mutect2, varscan2
- KIF21B | c.3584C>G p.T1195S | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV100144889; called by muse, mutect2, varscan2
- KIF21B | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1053127686; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIF7 | c.2800del p.E934Rfs*16 | Frame Shift Del (DEL) | VAF 81/364 reads (22%) | catalogued as COSV99177598; called by mutect2, pindel, varscan2
- KIF7 | c.2492T>C p.M831T | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1444851373, COSV101067114; called by muse, mutect2
- KIFC2 | c.888+8T>C | Splice Region (SNP) | VAF 54/199 reads (27%) | catalogued as rs757177795; called by muse, mutect2, varscan2
- KIR2DL4 | c.508C>T p.R170W (on ENST00000396284; = p.R131W on NM_001080770.2) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs747079301, COSV100610615; called by muse, varscan2
- KLHDC3 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs750701214; called by muse, varscan2
- KLHL28 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61887227; called by mutect2, varscan2
- KMT2A | c.10721C>T p.T3574M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); catalogued as rs782625001, COSV100630253, COSV63281937; called by muse, mutect2, varscan2
- KMT2D | c.5921C>T p.T1974M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777415982, COSV99040138; called by muse, mutect2, varscan2
- KNOP1 | c.957dup p.G320Rfs*5 | Frame Shift Ins (INS) | VAF 36/160 reads (23%) | catalogued as rs759734033; called by mutect2, varscan2
- KRT24 | c.402del p.L135Ffs*21 | Frame Shift Del (DEL) | VAF 45/167 reads (27%) | catalogued as rs1185702925; called by mutect2, pindel, varscan2
- KRT78 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771180780; called by muse, mutect2, varscan2
- KRT79 | c.298del p.A100Lfs*25 | Frame Shift Del (DEL) | VAF 35/158 reads (22%) | catalogued as COSV100398561; called by mutect2, varscan2
- KRT80 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs564779835; called by muse, mutect2, varscan2
- KRTAP1-4 | c.228del p.C77Afs*4 | Frame Shift Del (DEL) | VAF 78/342 reads (23%) | catalogued as rs773983457; called by mutect2, pindel, varscan2
- KRTAP12-2 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs375852477; called by mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 30/155 reads (19%) | catalogued as rs750491454; called by mutect2, varscan2
- L3MBTL1 | c.1703G>A p.R568Q (on ENST00000418998 / NM_001377303.1; = p.R478Q on NM_015478.7) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs777464489, COSV64228373; called by muse, mutect2, varscan2
- LAMA5 | c.7537C>T p.R2513C | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs762803716; called by muse, mutect2, varscan2
- LAMA5 | c.2482+2T>C p.X828_splice | Splice Site (SNP) | VAF 64/258 reads (25%) | catalogued as rs890168140; called by muse, mutect2, varscan2
- LARP4 | c.1118del p.N373Ifs*3 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs1179425728; called by mutect2, pindel, varscan2
- LAS1L | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56707899; called by muse, mutect2, varscan2
- LHCGR | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 123/372 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV54298317; called by muse, mutect2, varscan2
- LIFR | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 99/408 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372700087; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1L | c.777T>C p.V259= | Splice Region (SNP) | VAF 39/200 reads (20%) | catalogued as COSV100547730; called by muse, mutect2, varscan2
- LMO1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.722); catalogued as rs780757257, COSV59956410; called by muse, mutect2, varscan2
- LMX1A | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 40/180 reads (22%) | catalogued as rs1310771479, COSV54225542; called by muse, mutect2, varscan2
- LONRF2 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.031); catalogued as rs771136972; called by muse, mutect2, varscan2
- LRIF1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs778536278; called by muse, mutect2, varscan2
- LRP6 | c.2527G>C p.D843H | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99742210; called by muse, mutect2
- LRRC23 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs781881095, COSV50391722; called by muse, mutect2, varscan2
- LRRC3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764952626; called by muse, mutect2, varscan2
- LRRC36 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373608861, COSV99339077; called by muse, mutect2, varscan2
- LRRC7 | c.329G>A p.R110Q (on ENST00000651989 / NM_001370785.2; = p.R77Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs267598703, COSV50462590; called by muse, mutect2, varscan2
- LRRC8A | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 107/396 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs371265409; called by muse, mutect2, varscan2
- LRRTM1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54440605; called by muse, mutect2, varscan2
- LTBP4 | c.3538C>T p.R1180C (on ENST00000308370 / NM_001042544.1; = p.R1143C on NM_003573.2) | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1397661653, COSV52581164; called by muse, mutect2, varscan2
- MAMDC4 | c.1229dup p.V411Rfs*11 | Frame Shift Ins (INS) | VAF 48/205 reads (23%) | catalogued as rs1479024321; called by mutect2, pindel, varscan2
- MAN1B1 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769910765; called by muse, mutect2, varscan2
- MAN2B2 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs576269882; called by muse, mutect2, varscan2
- MAN2C1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs757278357; called by muse, mutect2, varscan2
- MAP2K2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 145/619 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as COSV53565066; called by muse, mutect2, varscan2
- MAP3K15 | c.521dup p.N174Kfs*20 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as rs745655024; called by mutect2, varscan2
- MAP4K4 | c.255T>A p.Y85* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as rs55856263; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99151282; called by muse, mutect2, varscan2
- MAPT | c.859C>T p.P287S (on ENST00000262410 / NM_001377265.1; = p.P212S on NM_016835.4) | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.257); catalogued as rs916080507; called by muse, mutect2, varscan2
- MARCHF7 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as rs149764354; called by muse, mutect2, varscan2
- MARCHF7 | c.1567del p.S523Vfs*13 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as COSV52031218; called by mutect2, pindel, varscan2
- MAST4 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV101282631; called by muse, mutect2
- MBP | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1206368278, COSV62829864; called by muse, mutect2, varscan2
- MCF2L | c.3218C>T p.A1073V (on ENST00000375608; = p.A1041V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV56177507; called by muse, mutect2, varscan2
- MCM9 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as rs1275424147, COSV60325493; called by muse, mutect2, varscan2
- MCTP1 | c.2618A>G p.E873G | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56502837; called by muse, mutect2, varscan2
- MCTP1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764728886; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 102/182 reads (56%) | catalogued as rs773080349; called by mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | catalogued as rs745558596; called by pindel, varscan2
- MEIG1 | c.48dup p.W17Mfs*19 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | catalogued as rs745512606; called by mutect2, pindel, varscan2
- MERTK | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs1259389572; called by muse, mutect2, varscan2
- METTL17 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as COSV59555336; called by muse, mutect2, varscan2
- METTL21C | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1486751770, COSV57433822; called by muse, mutect2, varscan2
- METTL2B | c.1097A>G p.Q366R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99299771; called by muse, mutect2, varscan2
- MFAP3L | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs576425047; called by muse, mutect2, varscan2
- MFAP5 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768885285, COSV63945029; called by muse, mutect2, varscan2
- MFSD14B | c.1269G>A p.Q423= | Splice Region (SNP) | VAF 12/126 reads (10%) | catalogued as rs1390723916; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs750307488; called by mutect2, varscan2
- MISP | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs372409482; called by muse, mutect2, varscan2
- MISP | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs772192185; called by muse, mutect2, varscan2
- MLXIPL | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 131/453 reads (29%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs782479538; called by muse, mutect2, varscan2
- MMP20 | c.359dup p.N120Kfs*9 | Frame Shift Ins (INS) | VAF 50/194 reads (26%) | catalogued as rs759614533; called by mutect2, varscan2
- MMP20 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs143867898; called by muse, mutect2, varscan2
- MMP24 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770843975; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as rs782038929; called by mutect2, varscan2
- MMP9 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 144/627 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV63434188; called by muse, mutect2, varscan2
- MRGPRF | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs139495945; called by muse, mutect2, varscan2
- MRGPRX3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs773230791, COSV101283576; called by muse, mutect2, varscan2
- MROH2B | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 55/216 reads (25%) | catalogued as rs770970800, COSV68186527; called by muse, mutect2, varscan2
- MRPL2 | c.873dup p.M292Hfs*64 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs71547829; called by pindel, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MSI1 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1280989341; called by muse, varscan2
- MTA1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58757272; called by muse, mutect2, varscan2
- MTNR1A | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as rs763220216, COSV56155885; called by muse, mutect2, varscan2
- MTNR1A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs764154841, COSV56155268; called by muse, mutect2, varscan2
- MTOR | c.2296del p.R766Dfs*11 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs746242022, COSV63872312; called by mutect2, pindel, varscan2
- MUC1 | c.245del p.P82Rfs*1029 (on ENST00000611571 / NM_001371720.1; = p.P82Rfs*242 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 73/297 reads (25%) | catalogued as COSV58118478; called by mutect2, pindel, varscan2
- MUC16 | c.1594del p.Q532Sfs*12 | Frame Shift Del (DEL) | VAF 81/266 reads (30%) | catalogued as COSV67460387; called by mutect2, varscan2
- MUC5B | c.14698G>A p.V4900M | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200106435; called by mutect2, varscan2
- MUC6 | c.148del p.A50Lfs*59 | Frame Shift Del (DEL) | VAF 86/368 reads (23%) | catalogued as rs760313765; called by mutect2, pindel, varscan2
- MXRA5 | c.6446del p.T2149Rfs*39 | Frame Shift Del (DEL) | VAF 68/155 reads (44%) | catalogued as COSV54236217; called by mutect2, pindel, varscan2
- MYBPC3 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as CM122971; called by muse, mutect2, varscan2
- MYH13 | c.3931G>A p.A1311T | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.41); catalogued as COSV99355175; called by muse, mutect2, varscan2
- MYH9 | c.4717C>A p.L1573M | Missense Mutation (SNP) | VAF 149/631 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53388792; called by muse, mutect2, varscan2
- MYO15B | c.6985C>T p.R2329W | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201541077; called by muse, mutect2, varscan2
- MYO5A | c.4840G>A p.V1614M | Missense Mutation (SNP) | VAF 171/590 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs775270803, COSV62560537; called by muse, mutect2, varscan2
- MYO7B | c.5927del p.K1976Rfs*5 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | catalogued as rs1388728830; called by mutect2, pindel, varscan2
- MYO9B | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV68282385; called by muse, mutect2, varscan2
- MYOZ2 | c.104del p.K35Rfs*47 | Frame Shift Del (DEL) | VAF 38/163 reads (23%) | catalogued as COSV61084721; called by mutect2, pindel, varscan2
- MYRF | c.1306G>A p.V436M (on ENST00000278836 / NM_001127392.3; = p.V427M on NM_013279.4) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs763288098; called by muse, mutect2, varscan2
- MZT2B | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1293614443; called by muse, mutect2, varscan2
- NAT16 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as rs977802076; called by muse, mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 68/305 reads (22%) | catalogued as rs1346393455; called by mutect2, pindel, varscan2
- NCAM1 | c.2447C>T p.T816M (on ENST00000316851 / NM_181351.5; = p.T806M on NM_000615.7) | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs914720238; called by muse, mutect2, varscan2
- NCAM2 | c.1907A>G p.E636G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs780905198; called by muse, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 88/352 reads (25%) | catalogued as rs772347389; called by mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 24/118 reads (20%) | catalogued as rs770284236; called by mutect2, varscan2
- NDRG2 | c.1040G>A p.R347H (on ENST00000298687 / NM_001354570.1; = p.R333H on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); catalogued as rs750366803; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs747914168; called by mutect2, varscan2
- NEUROD4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54470799, COSV54472887; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 62/248 reads (25%) | catalogued as rs752284115; called by mutect2, varscan2
- NFIC | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as rs374896582; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NKX2-1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.313); catalogued as COSV61387357; called by muse, mutect2, varscan2
- NMUR2 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV99677263; called by muse, mutect2, varscan2
- NOL10 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs761758951; called by muse, mutect2, varscan2
- NOS3 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.125); catalogued as rs773099942; called by muse, mutect2, varscan2
- NOS3 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs953325985, COSV52493594; called by muse, mutect2, varscan2
- NOSTRIN | c.1499G>A p.G500D (on ENST00000317647 / NM_001039724.4; = p.G422D on NM_052946.3) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.87); catalogued as rs751718907; called by muse, mutect2, varscan2
- NOX3 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs377545986; called by muse, mutect2, varscan2
- NPAT | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs1295384097; called by muse, mutect2, varscan2
- NPB | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763933748; called by muse, mutect2, varscan2
- NR0B1 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1470319256; called by muse, mutect2, varscan2
- NR2F2 | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as CM143724; called by muse, mutect2
- NRG2 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1322263180; called by muse, varscan2
- NSUN2 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as rs766236307; called by muse, mutect2, varscan2
- NTRK3 | c.1747A>G p.K583E | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs771172350; called by muse, mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 44/150 reads (29%) | catalogued as rs758695627; called by mutect2, varscan2
- NUP88 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370008628; called by muse, mutect2, varscan2
- NUP93 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs374772646; called by muse, mutect2, varscan2
- NUP98 | c.5024C>T p.A1675V (on ENST00000359171 / NM_001365126.1; = p.A1658V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.51); catalogued as rs1431951142; called by muse, mutect2, varscan2
- OBSCN | c.4658C>T p.T1553M | Missense Mutation (SNP) | VAF 114/581 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs765655321; called by muse, mutect2, varscan2
- ODAPH | c.225del p.P76Hfs*87 | Frame Shift Del (DEL) | VAF 76/327 reads (23%) | catalogued as COSV61141950; called by mutect2, pindel, varscan2
- ODF1 | c.275G>T p.R92M | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53432725; called by muse, mutect2, varscan2
- OPCML | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs374001465; called by muse, mutect2, varscan2
- OPN4 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs749934898; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 62/272 reads (23%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2G6 | c.854del p.L285* | Frame Shift Del (DEL) | VAF 58/246 reads (24%) | catalogued as COSV58573794; called by mutect2, pindel, varscan2
- OR4A16 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.404); catalogued as COSV100125070; called by muse, mutect2, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs749899868, COSV100237879; called by mutect2, pindel
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 130/451 reads (29%) | catalogued as rs755413956; called by mutect2, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OSBP2 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773762192; called by muse, mutect2, varscan2
- OTOF | c.5374C>T p.R1792C (on ENST00000272371 / NM_194248.3; = p.R1025C on NM_004802.4) | Missense Mutation (SNP) | VAF 180/674 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs142111099; ClinVar: uncertain significance; called by mutect2, varscan2
- OTOF | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 150/608 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778469940, COSV55507019; called by mutect2, varscan2
- OTOP1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs751957971; called by muse, mutect2, varscan2
- P2RX3 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.228); catalogued as COSV54442103; called by muse, mutect2, varscan2
- P2RY14 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs202142868; called by muse, mutect2, varscan2
- P4HA2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs750106952; called by muse, mutect2, varscan2
- PACRG | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as rs370616018; called by muse, mutect2, varscan2
- PAPOLG | c.1518G>A p.K506= | Splice Region (SNP) | VAF 36/80 reads (45%) | catalogued as rs1456041341; called by muse, mutect2, varscan2
- PAPPA2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs749472884, COSV100867290; called by muse, mutect2, varscan2
- PARG | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 97/481 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV71279971; called by muse, varscan2
- PARPBP | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs779839262, COSV59672544; called by muse, mutect2, varscan2
- PBRM1 | c.4551del p.P1518Lfs*21 (on ENST00000296302 / NM_001366071.2; = p.P1411Lfs*21 on NM_018313.5) | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs1559827261; called by mutect2, pindel, varscan2
- PCBP3 | c.795C>T p.P265= | Splice Region (SNP) | VAF 38/147 reads (26%) | catalogued as rs371552951, COSV68406926; called by muse, mutect2, varscan2
- PCDHA10 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 218/759 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs782288464, COSV100253124; called by muse, mutect2, varscan2
- PCDHB1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782222073, COSV60629965; called by muse, mutect2, varscan2
- PCDHB14 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 179/601 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV53386803, COSV53388667; called by muse, mutect2, varscan2
- PCDHB16 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 127/537 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV53358550; called by muse, mutect2, varscan2
- PCDHB5 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs561581411, COSV50658890; called by muse, mutect2, varscan2
- PCDHB7 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV50754123; called by muse, mutect2
- PCDHGC3 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99339504; called by muse, mutect2, varscan2
- PCK2 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1406489869; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 38/150 reads (25%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCSK6 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.575); catalogued as rs769260625, COSV100624188; called by muse, mutect2, varscan2
- PDE6B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 90/383 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs757048461, COSV55326588; called by muse, mutect2, varscan2
- PDHB | c.435del p.N148Mfs*7 | Frame Shift Del (DEL) | VAF 73/310 reads (24%) | catalogued as rs1438518070; ClinVar: benign; called by mutect2, pindel, varscan2
- PDLIM4 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 149/525 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs375520975, COSV99516680; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs759495724; called by mutect2, varscan2
- PFKP | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs369184858; called by muse, mutect2, varscan2
- PGGHG | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs572792323, COSV101164507; called by muse, mutect2, varscan2
- PGK2 | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 104/409 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100505404; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 40/72 reads (56%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHAX | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs760910428; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 55/104 reads (53%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PHKA2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV66056975; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs756552559; called by mutect2, varscan2
- PKD1 | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 176/743 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs150387925; called by muse, varscan2
- PKD1 | c.2085del p.A696Rfs*89 | Frame Shift Del (DEL) | VAF 69/315 reads (22%) | catalogued as CD010642; called by mutect2, pindel, varscan2
- PKD1L1 | c.5339del p.K1780Rfs*33 | Frame Shift Del (DEL) | VAF 39/178 reads (22%) | catalogued as rs1562955911; called by mutect2, pindel, varscan2
- PKHD1 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs139554269; called by mutect2, varscan2
- PKN1 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs781777991, COSV99661100; called by muse, mutect2, varscan2
- PKP3 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs144679997; called by muse, varscan2
- PKP3 | c.1390del p.L464Sfs*183 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | catalogued as rs757594408; called by pindel, varscan2
- PLCB2 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538647274; called by muse, mutect2, varscan2
- PLCB4 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781222515, COSV53802612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEK | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99311075; called by muse, mutect2, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLEKHG5 | c.984del p.L329Cfs*23 (on ENST00000400915 / NM_001042663.3; = p.L292Cfs*23 on NM_020631.6) | Frame Shift Del (DEL) | VAF 149/686 reads (22%) | catalogued as rs1348089546; called by mutect2, pindel, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PNISR | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1471118168; called by muse, mutect2, varscan2
- PNPLA7 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766414534; called by muse, mutect2, varscan2
- POC1B | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as rs867057656; called by muse, mutect2, varscan2
- POLR2E | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs372313949; called by muse, mutect2, varscan2
- POMT1 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs1465565429, COSV100586317; called by muse, mutect2, varscan2
- POTEE | c.2237del p.G746Afs*20 | Frame Shift Del (DEL) | VAF 128/698 reads (18%) | catalogued as rs1229339641; called by mutect2, varscan2
- POTEJ | c.1946del p.K649Rfs*6 | Frame Shift Del (DEL) | VAF 48/408 reads (12%) | catalogued as rs780515471; called by mutect2, varscan2
- PPFIA3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs1231037509; called by muse, mutect2, varscan2
- PPFIA3 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs775845994; called by muse, mutect2, varscan2
- PPID | c.85+2T>C p.X29_splice | Splice Site (SNP) | VAF 44/143 reads (31%) | catalogued as COSV100306772; called by muse, mutect2, varscan2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP1R13B | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs759732294, COSV52454093; called by muse, mutect2, varscan2
- PPP1R14B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.133); catalogued as rs750523503, COSV54185926; called by muse, mutect2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP2R5D | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55150861, COSV55151053; called by muse, mutect2, varscan2
- PRAME | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751654581, COSV67160962, COSV67161098; called by muse, mutect2, varscan2
- PRICKLE1 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 132/531 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs748173327, COSV58204493; called by muse, mutect2, varscan2
- PRICKLE1 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 138/557 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs572205675; called by muse, varscan2
- PRKDC | c.9137G>A p.R3046H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs373925433; ClinVar: uncertain significance; called by muse, varscan2
- PRMT1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV99773700; called by mutect2, varscan2
- PRMT5 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53546935; called by muse, mutect2, varscan2
- PROM1 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241309937; called by muse, mutect2, varscan2
- PROSER2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs770912396; called by muse, mutect2, varscan2
- PRR23A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs756899736, COSV67215202; called by muse, mutect2, varscan2
- PRR36 | c.1182del p.S395Rfs*8 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as rs1267178456; called by mutect2, pindel, varscan2
- PRRC2B | c.3277dup p.V1093Gfs*41 | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | catalogued as rs754941513; called by mutect2, varscan2
- PRRC2B | c.5120C>T p.A1707V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs573289081; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PRXL2A | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs755839655, COSV64690809; called by muse, mutect2, varscan2
- PSME4 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV66367017; called by muse, mutect2, varscan2
- PTCH1 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 121/450 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as rs779192138; ClinVar: uncertain significance; called by mutect2, varscan2
- PTK6 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV99420566; called by muse, mutect2, varscan2
- PTPN21 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs778405708, COSV60849590; called by muse, mutect2, varscan2
- PTPN6 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 98/414 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100016799; called by muse, mutect2, varscan2
- PTPRG | c.2165del p.N722Tfs*5 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs869306841; called by mutect2, pindel, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 78/300 reads (26%) | catalogued as rs772722517, COSV99560265; called by mutect2, varscan2
- RABL6 | c.2075A>G p.Q692R | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1314115901; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RAD50 | c.3154C>T p.Q1052* | Nonsense Mutation (SNP) | VAF 8/164 reads (5%) | catalogued as COSV54754306; called by muse, mutect2
- RAD52 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV99942554; called by muse, varscan2
- RAI1 | c.3965G>A p.R1322Q | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1204207609, COSV55394469, COSV55396084; called by muse, mutect2, varscan2
- RALGDS | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 225/857 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.484); catalogued as rs763143014; called by muse, mutect2, varscan2
- RAPGEF2 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1210462759; called by muse, mutect2, varscan2
- RAX2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs989493054; called by muse, mutect2, varscan2
- RBL2 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs17853303, COSV50878709; called by muse, mutect2, varscan2
- RBM24 | c.505G>A p.A169T (on ENST00000379052 / NM_001143942.2; = p.A124T on NM_153020.2) | Missense Mutation (SNP) | VAF 128/230 reads (56%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.985); catalogued as rs748372258, COSV59004065; called by muse, mutect2, varscan2
- RBP3 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs551138498; ClinVar: uncertain significance; called by muse, mutect2
- REXO5 | c.641del p.L214Yfs*9 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | catalogued as COSV99759517; called by mutect2, pindel, varscan2
- RFPL2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs984497336, COSV50710199; called by muse, mutect2, varscan2
- RHOBTB2 | c.708del p.K237Sfs*64 | Frame Shift Del (DEL) | VAF 72/277 reads (26%) | catalogued as rs1563291444; called by mutect2, pindel, varscan2
- RHOBTB2 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.82); catalogued as rs145553281; called by muse, mutect2, varscan2
- RIF1 | c.4490C>T p.A1497V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs750134324; called by muse, varscan2
- RIMBP3 | c.3499A>G p.M1167V | Missense Mutation (SNP) | VAF 157/927 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs527310654; called by muse, mutect2, varscan2
- RIMS2 | c.1022G>A p.R341H (on ENST00000666250 / NM_001348490.2; = p.R149H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1459469823, COSV51696368, COSV99158649; called by muse, mutect2, varscan2
- RNF157 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs756932914; called by muse, mutect2, varscan2
- RNF207 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs770911105; called by muse, mutect2, varscan2
- RNF213 | c.2180_2182del p.F727del | In Frame Del (DEL) | VAF 106/366 reads (29%) | catalogued as rs749634532; called by mutect2, varscan2
- RNF224 | c.48del p.P18Rfs*67 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs764684501; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 36/162 reads (22%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 52/246 reads (21%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO4 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.708); catalogued as rs1333624680; called by muse, mutect2, varscan2
- ROCK1 | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67696899; called by muse, varscan2
- RPGRIP1 | c.3638G>A p.S1213N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1340317371; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRP12 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs761936629; called by muse, mutect2, varscan2
- RSBN1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1202594576, COSV54731118; called by muse, mutect2, varscan2
- RSPH4A | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs757528263; called by muse, mutect2, varscan2
- RSPH4A | c.1818del p.W607Gfs*40 | Frame Shift Del (DEL) | VAF 84/320 reads (26%) | catalogued as rs748664881; called by mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs747510098; called by mutect2, varscan2
- RUNX3 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1361650293, COSV58245689; called by muse, mutect2, varscan2
- RUSC1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52741993; called by muse, mutect2, varscan2
- RUVBL2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55487752; called by muse, mutect2, varscan2
- RYR2 | c.6458A>G p.K2153R | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.487); catalogued as COSV63717110; called by muse, mutect2, varscan2
- S100A11 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1447849101; called by muse, mutect2, varscan2
- SALL3 | c.3314dup p.P1106Tfs*27 | Frame Shift Ins (INS) | VAF 46/230 reads (20%) | catalogued as rs749383364; called by mutect2, varscan2
- SCFD2 | c.152del p.G51Vfs*27 | Frame Shift Del (DEL) | VAF 43/214 reads (20%) | catalogued as rs753794117; called by mutect2, pindel, varscan2
- SCG2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs151247136; called by muse, mutect2, varscan2
- SCN4A | c.1843C>A p.L615M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs763346049; called by muse, mutect2, varscan2
- SCRIB | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771314329; called by muse, mutect2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SDHB | c.292T>G p.C98G | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM061959; called by muse, mutect2, varscan2
- SDHD | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs199901239; called by muse, mutect2, varscan2
- SDK1 | c.3067C>A p.L1023M | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV101268743; called by muse, mutect2, varscan2
- SEMA3G | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs1384023453; called by muse, mutect2, varscan2
- SEPTIN4 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs142115192; called by muse, mutect2, varscan2
- SERPINB12 | c.449del p.N150Tfs*39 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as rs760486497; called by mutect2, pindel, varscan2
- SERPINB2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs184826316, COSV55094443; called by muse, mutect2, varscan2
- SETD7 | c.1026del p.K344Rfs*14 | Frame Shift Del (DEL) | VAF 67/222 reads (30%) | catalogued as rs35259575; called by mutect2, pindel, varscan2
- SF3B2 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254825328; called by muse, mutect2, varscan2
- SFRP1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV55172961; called by muse, mutect2, varscan2
- SFRP1 | c.26del p.G9Afs*29 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs1436812585; called by mutect2, varscan2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs771387868; called by mutect2, varscan2
- SGSM2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 107/398 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370673706; called by muse, mutect2, varscan2
- SH3PXD2A | c.1154A>G p.N385S (on ENST00000369774 / NM_001365079.1; = p.N357S on NM_014631.2) | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1564844090; called by muse, mutect2, varscan2
- SH3TC1 | c.1574G>A p.W525* | Nonsense Mutation (SNP) | VAF 43/170 reads (25%) | catalogued as rs1220739918; called by muse, mutect2, varscan2
- SHANK2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs189053721; called by muse, mutect2, varscan2
- SHANK3 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs1211067917; called by muse, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 66/241 reads (27%) | catalogued as rs746556543; called by mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SIPA1L3 | c.378del p.T127Pfs*96 | Frame Shift Del (DEL) | VAF 66/344 reads (19%) | catalogued as COSV55910829; called by mutect2, pindel, varscan2
- SIRT2 | c.705dup p.G236Wfs*2 | Frame Shift Ins (INS) | VAF 23/119 reads (19%) | catalogued as rs1350730903; called by mutect2, pindel, varscan2
- SIRT3 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61501532; called by muse, mutect2, varscan2
- SLAMF8 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 70/309 reads (23%) | catalogued as rs752748736, COSV56987465; called by muse, mutect2, varscan2
- SLC18B1 | c.173del p.F58Sfs*17 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1245585349, COSV51593409; called by mutect2, pindel, varscan2
- SLC26A3 | c.1407T>C p.C469= | Splice Region (SNP) | VAF 12/222 reads (5%) | catalogued as rs1232510324; called by muse, mutect2
- SLC26A6 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751147237, COSV99374356; called by muse, mutect2, varscan2
- SLC2A12 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV99260562; called by muse, mutect2, varscan2
- SLC30A3 | c.613del p.H205Tfs*260 | Frame Shift Del (DEL) | VAF 63/275 reads (23%) | catalogued as rs745429257; called by mutect2, pindel, varscan2
- SLC39A6 | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52367586; called by muse, mutect2, varscan2
- SLC4A3 | c.1340A>T p.N447I | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs752178824; called by muse, mutect2, varscan2
- SLC5A2 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 178/658 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373855573; called by muse, varscan2
- SLC7A13 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.076); catalogued as COSV99878318; called by muse, mutect2
- SLC8A1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60472469, COSV60499841; called by muse, mutect2, varscan2
- SLC9A5 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs761851419; called by muse, mutect2, varscan2
- SLITRK5 | c.2393C>A p.P798Q | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs952935728, COSV61523924; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs760667210; called by mutect2, varscan2
- SMO | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as rs116193648, COSV99976598; called by mutect2, varscan2
- SNRNP40 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs781004017, COSV55279068; called by muse, mutect2, varscan2
- SNX19 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1565560727; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX8 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs775447474; called by muse, mutect2, varscan2
- SOHLH1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 135/488 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1200856784; called by muse, mutect2, varscan2
- SOX11 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV58987857; called by muse, mutect2, varscan2
- SOX13 | c.1010del p.P337Rfs*69 | Frame Shift Del (DEL) | VAF 38/149 reads (26%) | catalogued as rs1362904355; called by mutect2, pindel, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SOX8 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs555677616; called by muse, mutect2, varscan2
- SPG11 | c.2849del p.L950Wfs*13 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | catalogued as CD166713; called by mutect2, pindel, varscan2
- SPRED3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs776040740; called by muse, varscan2
- SPTA1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 64/346 reads (18%) | catalogued as rs764157190, COSV63751440; called by muse, mutect2, varscan2
- SPTBN1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372175923; called by muse, varscan2
- SPTBN1 | c.6320C>T p.T2107M | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs766647948, COSV61690257; called by muse, mutect2, varscan2
- SSC5D | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs575176406, COSV67476896; called by muse, mutect2, varscan2
- STAT5A | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV61805608; called by muse, mutect2, varscan2
- STXBP3 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750050452, COSV64181653; called by muse, mutect2, varscan2
- SYCE1L | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs985783726; called by muse, mutect2, varscan2
- SYCP2 | c.3515C>T p.A1172V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs1272299768; called by muse, mutect2, varscan2
- SYCP2L | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1297729330; called by muse, mutect2, varscan2
- SYNE2 | c.16244G>T p.S5415I | Missense Mutation (SNP) | VAF 96/440 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs377399289; called by muse, mutect2, varscan2
- TAB1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 84/303 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs781515810, COSV53372153; called by muse, mutect2, varscan2
- TAF4 | c.2564C>T p.T855M | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755495702, COSV53341116; called by muse, mutect2, varscan2
- TBC1D14 | c.1229T>G p.V410G | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63391717; called by muse, mutect2, varscan2
- TBL1XR1 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs374745294; called by muse, mutect2, varscan2
- TBX2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.235); catalogued as rs1292917610; called by mutect2, varscan2
- TBX3 | c.420T>G p.C140W | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57473647; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 88/354 reads (25%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCEA2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs373707539; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | catalogued as rs748021112; called by mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 44/181 reads (24%) | catalogued as rs763438715; called by mutect2, varscan2
- TDRP | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1418572853, COSV60705328; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 36/164 reads (22%) | catalogued as rs763321097; called by mutect2, varscan2
2,122 further variants in this file (1,191 protein-altering or splice-affecting, 540 silent, 391 other) are not listed here.
